TCGA case TCGA-VD-A8KF — Uveal Melanoma (TCGA-UVM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa; Tissue source site: University of Liverpool. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/78039723-94a9-4903-8bb4-c00852e8e889

Demographics
Sex at birth: male; Country of residence at enrollment: United Kingdom; Age at index: 68 years; Vital status: Dead; Days to death: 40 days; Cause of death: Cancer Related.

Diagnoses (2)
1. Mixed epithelioid and spindle cell melanoma (the primary disease): ICD-O-3 morphology code: 8770/3; ICD-10 code: C69.80; Tissue or organ of origin: Overlapping lesion of eye and adnexa; Site of resection or biopsy: Overlapping lesion of eye and adnexa; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 68.6 years (25,066 days); Year of diagnosis: 2013; Method of diagnosis: Enucleation; AJCC staging edition: 7th; AJCC clinical T: T4b; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IIIB; AJCC pathologic T: T4b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIB; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 40 days; Sites of involvement: Eye, Choroid / Eye, Ciliary Body.
   Pathology details: Measurement type: Echographic; Tumor basal diameter: 19.2.
   Pathology details: Additional pathology findings: Extravascular Matrix Loops; Consistent pathology review: Yes; Epithelioid cell percent range: 61-90%; Extrascleral extension present: No; Measurement type: Echographic; Tumor depth measurement: 7.2; Tumor infiltrating lymphocytes: Few; Tumor shape: Diffuse.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Mixed epithelioid and spindle cell melanoma). Prior treatment: Yes.

Follow-up (2 entries)
- Days to follow up: 40 days; Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Timepoint: Post Initial Treatment.

Molecular and laboratory tests
- Test (Cytogenetics, NOS): Positive.
- Test (Cytogenetics, NOS): Positive; Chromosome arm: q.
- Test (Microscopy, NOS): Mitotic Count Reported; Mitotic count: 16.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VD-A8KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 120 mg.
  Slide TCGA-VD-A8KF-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VD-A8KF-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-VD-A8KF-10A, TCGA-VD-A8KF-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Cause of death: Metastatic Uveal Melanoma.
- Primary pathology, Tumor tissue site list: Submitted tumor site: Choroid; Submitted tumor site: Ciliary body.
- Primary pathology, Tumor morphology list, Tumor morphology: Histologic diagnosis: Epithelioid Cell.
- Primary pathology, Cytogenetic abnormality list: Cytogenetic abnormality type: Chromosome 3 loss; Cytogenetic abnormality type: Chromosome 8q gain.
- Primary pathology: Extravascular matrix patterns: Loops; Tumor basal diameter mx: Echographic Measurement; Tumor thickness measurement: Echographic Measurement.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 40 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 40 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 40 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VD-A8KF-01A-11D-A39V-01): tumor purity 1, ploidy 2.01, whole-genome doublings 0.
